TCGA case TCGA-V5-AASW — Esophageal Carcinoma (TCGA-ESCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus; Tissue source site: Duke University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ad2fe57c-2f44-4d57-83a9-349c8a25c414

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 72 years; Vital status: Alive; Country of birth: United States.

Diagnoses (3)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C15.9; Tissue or organ of origin: Esophagus, NOS; Site of resection or biopsy: Esophagus, NOS; Classification of tumor: primary; Age at diagnosis: 72.7 years (26,571 days); Method of diagnosis: Biopsy; AJCC staging edition: 7th; AJCC clinical T: T3; AJCC clinical N: N1; AJCC clinical M: M0; AJCC clinical stage: Stage IIIA; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 282 days; Cancer detection method: Symptomatic; Esophageal columnar dysplasia degree: High Grade Dysplasia; Esophageal columnar metaplasia present: Yes; Goblet cells columnar mucosa present: Yes; Sites of involvement: Esophagus, Middle Third / Esophagus, Lower Third.
   Pathology details: Consistent pathology review: Yes; Lymph node involvement: Positive.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant.
2. Metastasis of diagnosis 1 (Adenocarcinoma, NOS), site: Lung, NOS. Age at diagnosis: 73.5 years (26,853 days); Days to diagnosis: 282 days; Prior treatment: Yes.
   Recorded as not given: Surgery, NOS, for progressive disease; Surgery, NOS, for recurrent disease.
3. Metastasis of diagnosis 1 (Adenocarcinoma, NOS), site: Liver. Age at diagnosis: 73.5 years (26,853 days); Days to diagnosis: 282 days; Prior treatment: Yes.
   Recorded as not given: Surgery, NOS, for progressive disease.

Follow-up (5 entries)
- Days to follow up: 248 days; Disease response: With Tumor.
- Day 282 (post initial treatment): Disease response: With Tumor; Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 282 days; Evidence of progression type: Convincing Image Source.
- Day 282 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 282 days; Evidence of recurrence type: Convincing Image Source.
- Day 282 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 282 days; Evidence of progression type: Convincing Image Source.
- Karnofsky performance status: 60; ECOG performance status: 2.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: GERD; Reflux treatment type: Surgically Treated; Risk factors: GERD.
- Timepoint category: Initial Diagnosis; Weight: 88 kg; Height: 175 cm; BMI: 28.7.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-V5-AASW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 20 mg.
  Slide TCGA-V5-AASW-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-V5-AASW-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-V5-AASW-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Cancer procurement state province: NC; Cancer procurement city: Durham; History neoadjuvant treatment: No; Tumor status: With tumor; Tobacco smoking history indicator: 2; Alcohol history documented: No; History reflux disease indicator: Yes; History hpylori infection indicator: Never; History barretts esophageal indicator: No; Number of relatives diagnosed: 0.
- Antireflux treatment types: History reflux disease treatment: Medically Treated.
- Primary pathology: Esophageal tumor location centered: Mid; Histologic diagnosis: Esophagus Adenocarcinoma, NOS; Method initial path diagnosis: Endoscopic Biopsy; Lymph node sprd radiograph evidence: Yes; Patient to undergo surgery: Yes.
- Primary pathology, Esophageal tumor involvement sites: Esophageal tumor location involved: Mid; Esophageal tumor location involved: Distal.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 282 days; disease-specific survival: no event (censored), 282 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 282 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-V5-AASW-01A-11D-A402-01): tumor purity 0.73, ploidy 2.75, whole-genome doublings 1.
